Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-A4CI, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-A4CI-01A (Primary Tumor).

[page 1 of 6]
Department of Pathology

Patient Name: [REDACTED]	Service: Otolaryngology	Copath #: [REDACTED]
MRN: [REDACTED]	Visit #: [REDACTED]	Collected: [REDACTED]
DOB: [REDACTED]	Location: [REDACTED]	Resulted: [REDACTED]
Gender: [REDACTED]	Facility: [REDACTED]	
HCN: [REDACTED]		
Ordering MD: [REDACTED]		

Surgical Pathology Consultation Report

1CD-0-3

* Addended *

Carcinoma, basaloid squamous cell
8083/3

SPECIMEN(S) RECEIVED

CRCF Site: buccal mucosa C 06.0

1. Nck: RIGHT LEVEL 1
2. Nck: RIGHT LEVEL 2
3. Nck: RIGHT LEVEL 3 / 5B
4. Nck: RIGHT LEVEL 4 / 5B
5. Oral Cavity: Inferior right maxilla and buccal mucosa, long stitch anterior, short buccal
6. Muscle: deep pterygoid margin
7. Fat: retroantral fat

Path. oral cavity, NOS C60.9 9/26/12
μ

DIAGNOSIS

1, 2, 3 and 4. Right neck dissection; levels I, II, III-V, and IV-VB. One of forty-nine lymph nodes positive for squamous cell carcinoma (1/49).

- a. The involved lymph node measures 1.2 cm.
- b. Negative for extracapsular invasion.
- c. The involved lymph node is in level I.
- d. Submandibular gland with no pathologic changes. Negative for carcinoma.

5. Oral cavity; inferior right maxilla and buccal mucosa. Basaloid squamous cell carcinoma, poorly differentiated.

- a. Maximum tumour dimension 3.0 cm.
- b. Tumour thickness 1.7 cm.
- c. Positive for lymphovascular invasion.
- d. Negative for perineural invasion.
- e. Margins negative for tumour. The tumour is close (< 0.1 cm) to the deep superolateral margin.
- f. Sections of bone are pending. An addendum report will follow.

6 and 7. Deep pterygoid margin, and retro-antral fat.

[page 2 of 6]
Negative for carcinoma.

Status: supplemental

Page: 1 of 5

Patient Name: [REDACTED]	Service: Otolaryngology	Copath #: [REDACTED]
MRN: [REDACTED]	Visit #: [REDACTED]	Collected: [REDACTED]
DOB: [REDACTED]	Location: [REDACTED]	Resulted: [REDACTED]
Gender: [REDACTED]	Facility: [REDACTED]	
HCN: [REDACTED]		
Ordering MD: [REDACTED]		

SYNOPTIC DATA

Specimen:	Upper gingiva (gum) Buccal mucosa (inner cheek) Maxilla Fresh Maxillectomy: right inferior Neck (lymph node) dissection: right
Received:	
Procedure:	
maxillectomy and buccal mucosa	
neck dissection I-VB	
Specimen Size:	Greatest dimension: 6.5 cm Additional dimension: 5.2 cm Additional dimension: 4.0 cm
Specimen Laterality:	Right
Tumor Site:	Upper gingiva (gum) Buccal mucosa (inner cheek) Maxilla Single focus Greatest dimension: 3.0 cm Basaloid squamous cell carcinoma G3: Poorly differentiated Margins uninvolved by invasive
Tumor Focality:	
Tumor Size:	
Histologic Type:	
Histologic Grade:	
Margins:	
carcinoma	Distance from closest margin: 0.05
cm	Margin(s): superolateral deep margin Margin status for carcinoma in situ
is not applicable	
Lymph-Vascular Invasion:	Present
Perineural Invasion:	Not identified
Lymph Nodes, Extranodal Extension:	Not identified
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT2: Tumor more than 2 cm but not

[page 3 of 6]
more than 4 cm in greatest dimension

Regional Lymph Nodes (pN):

ipsilateral lymph node, 3 cm or less

examined: 49

involved: 1

pN1: Metastasis in a single
in greatest dimension

Number of regional lymph nodes

Number of regional lymph nodes

Status: supplemental

Page: 2 of 5

Patient Name: [REDACTED]

MRN: [REDACTED]

DOB: [REDACTED]

Gender: [REDACTED]

HCN: [REDACTED]

Ordering MD: [REDACTED]

Service: Otolaryngology

Visit #: [REDACTED]

Location: [REDACTED]

Facility: [REDACTED]

Copath # [REDACTED]

Collected: [REDACTED]

Resulted: [REDACTED]

Distant Metastasis (pM):

Not applicable

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

ELECTRONICALLY VERIFIED BY:

GROSS DESCRIPTION

1. The specimen is labeled with the patient's name and as "Neck: Right level 1". The specimen consists of fibroadipose tissue that measures 8.0 x 4.0 x 2.0 cm. The submandibular gland is unremarkable and measures 4.0 x 3.0 x 2.0 cm. The remaining specimen demonstrates multiple lymph nodes ranging in maximum dimension from 0.3 to 1.2 cm.

1A submandibular gland

1B 3 lymph nodes

1C 1 lymph node

2. The specimen container is labeled with the patient's name and as "Neck: Right level 2". The specimen consists of fibroadipose tissue that measures 3.5 x 3.0 x 1.4 cm. Multiple lymph nodes are identified ranging from 0.2 to 2.0 cm.

2A multiple lymph nodes

2B multiple lymph nodes

2C multiple lymph nodes

[page 4 of 6]
2D 3 lymph nodes
2E 1 lymph node

3. The specimen is labeled with the patient's name and as "Neck: Right level 3/5B". The specimen consists of fibroadipose tissue that measures 3.5 x 4.0 x 2.2 cm. The tissue also includes a portion of unremarkable muscle measuring 3.5 x 1.9 x 0.8 cm. Multiple lymph nodes that range from 0.1 to 1.5 cm are identified.

3A multiple lymph nodes
3B two lymph nodes
3C multiple lymph nodes
3D 1 lymph node

Status: supplemental

Page: 3 of 5

Patient Name: [REDACTED]	Service: Otolaryngology	Copath #: [REDACTED]
MRN: [REDACTED]	Visit #: [REDACTED]	Collected: [REDACTED]
DOB: [REDACTED]	Location:	Resulted: [REDACTED]
Gender: [REDACTED]	Facility:	
HCN:		
Ordering MD: [REDACTED]		

4. The specimen is labeled with the patient's name and as "Neck: Right level 4/5B". The specimen consists of fibroadipose tissue that measures 3.0 x 3.0 x 1.1 cm. Multiple lymph nodes that range from 0.1 to 1.2 cm are identified.

4A three lymph nodes
4B five lymph nodes
4C three lymph nodes

5. The specimen is labeled with the patient's name and as "Inferior right maxilla & buccal mucosa; stitch long anterior; short buccal". It consists of an oriented en bloc resection of a segment of right maxilla with adjacent buccal mucosa measuring 6.5 AP x 5.2 SI x 4.0 ML cm. The maxilla has no teeth. There is a tumor arising in the oral mucosa at the junction of the maxillary gingival mucosa and buccal mucosa. The tumor measures 3.0 AP x 1.7 SI x 2.2 ML cm on the surface of the mucosa. It has a maximum thickness of 1.7 cm. The tumor is white-tan and firm. There is no gross involvement of bone by the tumour. The tumor is located at <0.1 cm from the closest (superolateral) deep margin. The distance from the tumor to the remaining margins: anterior mucosa and soft tissue 0.6 cm, posterior mucosa and soft tissue 1.0 cm, inferior buccal mucosa and soft tissue 0.6 cm, medial gingival mucosa and soft tissue 0.3 cm, anterior mandible bone margin 0.8 cm, superior bone

[page 5 of 6]
margins 0.5 cm. Received separately is a portion of paper-thin bone measuring 1.5 x 1.3 x 0.1 cm. Multiple pieces of tissue are stored frozen. Representative sections are submitted.

- 5A tumor with anterior mucosa and soft tissue margin
- 5B tumor with posterior mucosa and soft tissue margin
- 5C tumor with inferior buccal mucosa and soft tissue margin
- 5D tumor with medial gingival mucosa and soft tissue margin
- 5E-5F tumor with superolateral deep margin
- 5G anterior mandibular resection margin, en face (decalcification)
- 5H superior bony margins, en face (decalcification)
- 5I posterior bony margins, en face (decalcification)
- 5J separate piece of bone serially sectioned (decalcification)
- 5K tumor with bone (decalcification)

6. The specimen is labeled with the patient's name and as "Deep pterygoid margin". It consists of 3 pieces of tissue measuring 0.6 x 0.4 x 0.3 cm, 0.2 x 0.2 x 0.2 cm and 0.2 x 0.1 x 0.1 cm. The specimen is submitted in toto for frozen section.

6A frozen section control

Status: supplemental

Page: 4 of 5

Patient Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED]
Gender: [REDACTED]
HCN: [REDACTED]
Ordering MD: [REDACTED]

Service: Otolaryngology
Visit #: [REDACTED]
Location:
Facility:

Copath #: [REDACTED]
Collected: [REDACTED]
Resulted: [REDACTED]

7. The specimen is labeled with the patient's name and as "Retro-antral fat". It consists of a piece of adipose tissue measuring 1.7 x 0.4 x 0.2 cm. The specimen is submitted in toto for frozen section.

7A frozen section control

QUICK SECTION

6. Deep pterygoid margin: Negative for carcinoma.

7. Retro- antral fat: Negative for carcinoma.

Result reported to the

[page 6 of 6]
Addendum Status: Signed Out
Date Reported:

Addendum Comment
Decalcified sections show focal invasion of periosteum by squamous cell carcinoma. The bone margins are negative for tumor.

Status: supplemental

Page: 5 of 5

Equal, Synchronous Primary Noted		☒

8/22/12

Source: NCI Genomic Data Commons file 5740ca93-03fc-4e4b-9f90-c6a02d6326b5 (TCGA-CQ-A4CI.A97C5531-8FCD-4054-9C07-0E38B4954657.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).